Gene-level copy-number profile of tumor specimen TCGA-MP-A4SW-01A from TCGA case TCGA-MP-A4SW, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 53.8 years (19,640 days).
Specimen TCGA-MP-A4SW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.241b179d-c08c-4d0d-bc13-9480aa0d638a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MP-A4SW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3be8b801-b6d2-4e02-9336-60050e0cb9d0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 10,943; copy number 2: 34,247; copy number 3: 9,391; copy number 4: 2,172; copy number 5: 2,101; copy number 6: 648; copy number 7: 97; copy number 8: 214; copy number 9: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MP-A4SW-01A-21D-A24O-01): tumor purity 0.46, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:123,485,529–123,493,156, 2 genes: MIR7150, AL445489.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,065 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:1,725,149–4,041,764, 30 genes, copy number 5: AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1.
- chr7:54,933,699–56,617,957, 69 genes, copy number 7–9 (broad region; genes not listed).
- chr8:76,162,119–145,066,685, 1,077 genes, copy number 5–8 (broad region; genes not listed).
- chr12:459,939–2,004,535, 30 genes, copy number 7: B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B.
- chr12:2,004,666–2,049,463, 3 genes, copy number 7: AC005342.1, CACNA1C-IT1, CACNA1C-IT2.
- chr16:11,555–35,912,516, 1,419 genes, copy number 5 (broad region; genes not listed).
- chr19:32,963,499–41,506,898, 437 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,279. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
